Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A48V, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A48V-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient:

Clinical Diagnosis & History:

year old with large right retroperitoneal sarcoma encasing vena cava
biopsy (+) leiomyosarcoma.

Specimens Submitted:

1: SP: Abdominal leiomyosarcoma

ICD-O3

leiomyosarcoma, NOS

8890/3

Sit = CQCF: Retroperitoneum

C48.0

Path: Vena cava, NOS

9-11-12

RD

C49.4

DIAGNOSIS:

1. SOFT TISSUE, RETROPERITONEAL; RESECTION:

-HIGH GRADE LEIOMYOSARCOMA INVOLVING WALL OF VENA CAVA.

-TUMOR DIMENSIONS: 14 X 13 X 10 CM.

-FOCAL NECROSIS (LESS THAN 10%) IS PRESENT.

-SURGICAL MARGINS (SOFT TISSUE AND VENA CAVA) ARE FREE OF TUMOR.

FOCALLY THE TUMOR IS WITHIN 0.2 CM OF SOFT TISSUE MARGIN, HOWEVER IS WELL
LIMITED BY FIBROUS MEMBRANOUS TISSUE AND ADIPOSE TISSUE.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF
THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED
THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh labeled "abdominal leiomyosarcoma" and
consists of an irregular soft tissue mass with dimensions of 16 x 14 x 11
cm. The specimen is covered by ragged fat, focal skeletal muscle, patches of
peritoneum, and a focal thin fibrous membrane. There is an adherent 9 cm
segment of vein with a diameter of 1 cm that is stapled at both ends.
Sectioning reveals a well-circumscribed tumor with dimensions of 14 x 13 x
10 cm. The tumor has a tan, rubbery, whorled cut surface with central
hemorrhage and white fibrous areas. No gross necrosis is identified. The
tumor appears to invade the surrounding fat with a pushing border. The tumor
is adherent to the large vessel but does not appear to extend to the entire
wall. The endothelial surface is tan and smooth. The tumor abuts the thin

** Continued on next page **

[page 2 of 2]
SURGICAL

----- Page 2 of 2
fibrous capsule. Gross photographs are taken, tissue is submitted for TPS,
and representative sections are submitted.

Summary of sections:

TP-tumor to peritoneum.

TF-tumor to fibrous membrane

TM-tumor to muscle

TV-tumor to vessel

VM-vessel margins.

T-tumor representative sections

Summary of Sections:

Part 1: SP: Abdominal leiomyosarcoma

Block	Sect.	Site	PCs
10		T	10
1		TF	1
1		TM	1
1		TP	1
2		TV	2
1		VM	2

** End of Report **

Source: NCI Genomic Data Commons file 30b258f3-2681-49b2-ad85-3c6dec2e1fb2 (TCGA-DX-A48V.9FC2DC07-1AB2-48E9-B342-639E1C478A31.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).